Somatic mutation profile of tumor specimen TARGET-10-PATZYC-09A (aliquot TARGET-10-PATZYC-09A-01D) from TARGET case TARGET-10-PATZYC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,350 days).
Specimen TARGET-10-PATZYC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28e456de-62d6-4dfe-9dc4-48298541e6a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATZYC-10A (Blood Derived Normal), aliquot TARGET-10-PATZYC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b018e769-61f0-4658-8f61-f5d2db351714

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STAT5B | c.1924A>C p.N642H | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.949); catalogued as rs938448224, COSV53180204; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ATF1 | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50395340; called by muse, mutect2, varscan2
- DOT1L | c.973T>G p.Y325D | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67112195; called by muse, mutect2, varscan2
- GATA3 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60516183; called by muse, mutect2, varscan2
- KIRREL3 | c.1244C>T p.T415I | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.911); catalogued as rs1435082943, COSV69385736; called by muse, mutect2, varscan2
- LCE2D | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.055); catalogued as rs753899892, COSV64228947, COSV64229148; called by muse, mutect2, varscan2
- MAGI1 | c.2558G>A p.R853H (on ENST00000402939 / NM_001033057.2; = p.R881H on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375197593, COSV58337552; called by muse, mutect2, varscan2
- SRPK1 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.508); catalogued as COSV60413312; called by muse, mutect2, varscan2
- THSD4 | c.1288G>A p.V430I | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs552707681, COSV55979007; called by muse, mutect2, varscan2
- UBAP1 | c.1226T>C p.V409A | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV52660585; called by muse, mutect2, varscan2
- IL2RB | c.1477C>T p.L493= | Silent (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- KIF7 | c.3153C>T p.A1051= | Silent (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2
- MOGS | c.342C>T p.P114= | Silent (SNP) | VAF 18/35 reads (51%) | called by muse, mutect2, varscan2
- A2M | chr12:9064558 G>A | 3'Flank (SNP) | VAF 10/10 reads (100%) | catalogued as rs910000818; called by muse, mutect2, varscan2
